Somatic mutation profile of tumor specimen MP2PRT-PATJJY-TBP1-A (aliquot MP2PRT-PATJJY-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATJJY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 1.4 years (507 days).
Specimen MP2PRT-PATJJY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 511e872f-9503-4be4-834c-836bcd414589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJJY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJJY-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/705b6537-3a5c-4fb0-9e9c-7178b597e2b6

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP2 | c.656T>C p.M219T | Missense Mutation (SNP) | VAF 52/698 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- HLA-DMA | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 48/930 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYPOP | c.187A>T p.I63F | Missense Mutation (SNP) | VAF 46/879 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2
- NCKAP5 | c.3914C>T p.T1305I | Missense Mutation (SNP) | VAF 18/561 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPRY3 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 56/779 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- JMJD4 | c.186G>A p.L62= | Silent (SNP) | VAF 107/579 reads (18%) | catalogued as rs781766280, COSV59918526; called by muse, mutect2, varscan2
- NAGLU | c.1353C>T p.N451= | Silent (SNP) | VAF 33/637 reads (5%) | catalogued as rs200029453, COSV56794350; ClinVar: likely benign; called by muse, mutect2
